Gene-level copy-number profile of tumor specimen HCM-BROD-0477-C16-06A from HCMI case HCM-BROD-0477-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 68.6 years (25,046 days).
Specimen HCM-BROD-0477-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9af38ca-b764-4524-bc8e-81381c99626d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0477-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/809ea1e4-8a58-47f6-973f-92caf46da623

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 12,786; copy number 2: 42,586; copy number 3: 3,333; copy number 4: 54; copy number 5: 81; copy number 6: 11; copy number 11: 10; copy number 19: 11; copy number 23: 3.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene: AC113430.1.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr12:133,238,335–133,238,549, 2 genes: RNU6-717P, Y_RNA.
- chr13:114,306,646–114,337,626, 3 genes: CLCP2, CHAMP1, LINC01054.
- chr15:51,952,106–53,762,878, 30 genes (within-gene range 0–2): MAPK6, MAPK6-DT, AC090970.2, AC090970.1, AC023906.5, AC023906.2, AC023906.1, BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C, MIR1266, MYO5A, EEF1B2P1, ARPP19, AC025917.1, FAM214A, AC009754.1, AC009754.2, ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1, WDR72, RNU2-53P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 116 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,358,566–109,441,171, 74 genes, copy number 5–23 (within-gene range 3–23) (broad region; genes not listed).
- chr8:38,699,274–39,580,134, 17 genes, copy number 5–6: AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr21:24,840,550–25,772,460, 25 genes, copy number 5–6: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2.

Autosomal genes at a single copy (total copy number 1): 10,444. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
